Surgical pathology report (de-identified scan), TCGA case TCGA-AP-A1E1, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site MSKCC, specimen TCGA-AP-A1E1-01A (Primary Tumor).

[page 1 of 2]
ICB-0-3

Adenocarcinoma, endometrioid, NOS 8380/3

Site Code: Endometrium C54.1

TSS Name/##:

1/12/11
lw

Specimens Submitted:

- 1: SP: Uterus, cervix, bilateral fallopian tubes and ovaries; total abdominal hysterectomy and bilateral salpingo-oophorectomy
- 2: SP: Sentinel lymph node, right external iliac; biopsy
- 3: SP: Sentinel lymph node, left external iliac; biopsy

DIAGNOSIS:

1. SP: Uterus, cervix, bilateral fallopian tubes and ovaries; total abdominal hysterectomy and bilateral salpingo-oophorectomy:

Tumor Type:

Adenocarcinoma, endometrioid type

Architectural Grade (For Endometrioid Types only):

II (6-50% solid growth)

Nuclear Grade (For Endometrioid Types only):

Grade 2

FIGO Grade (For Endometrioid Types only):

Grade 2

Myometrial Invasion:

(=<50%)

Measures 3mm in maximum depth

Myometrium thickness measures 30mm in the area of maximal tumor

invasion

Endocervical Invasion:

Not identified

Lymphovascular invasion:

Not identified

Endometrium:

Unremarkable

Myometrium:

Exhibits adenomyosis

Adnexa:

Unremarkable

2. SP: SENTINEL LYMPH NODE, RIGHT EXTERNAL ILIAC; BIOPSY:

-ONE BENIGN LYMPH NODE (0/1)

-MULTIPLE LEVELS AND CYTOKERATIN IMMUNOSTAINED SECTIONS ARE EXAMINED

** Continued on next page **

[page 2 of 2]
TSS Name/#

Page 2 of 4

3. BP: SENTINEL LYMPH NODE, LEFT EXTERNAL ILIAC; BIOPSY:
- ONE BENIGN LYMPH NODE (0/1)
- MULTIPLE LEVELS AND CYTOKERATIN IMMUNOSTAINED SECTIONS ARE EXAMINED

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON THE PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL) BY THE PATHOLOGIST WHOSE NAME APPEARS ABOVE MINE, AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Source: NCI Genomic Data Commons file 3af67989-8da9-4b9c-976b-00d1ec660105 (TCGA-AP-A1E1.E8873536-294D-4E41-9165-EE403A11B439.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).